Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A4DS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A4DS-01A (Primary Tumor).

[page 1 of 2]
Pre-Malignancy History		/

ANATOMIC PATHOLOGY REPORT
PERMANENT CHART COPY
(Chart in Operative/Procedural Section)

1cd-0-3

Astrocystoma, anaplastic 9401/3

CQCE Site: Supratentorial brain, Nos C71.0

Path: Brain, nos C71.9 pw 9/25/12

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Brain tumor, FS
2. Brain tumor enhancing portion, FS
3. Brain tumor enhancing portion #2, FS
4. Brain tumor

CLINICAL DIAGNOSIS:

Dx: Brain tumor

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name and "brain tumor" consists of multiple irregular tan-white to pink soft tissue fragments aggregating to 0.7 x 0.4 x 0.3 cm. A smear preparation is prepared and examined. The specimen is submitted in its entirety for frozen section on one chuck with residual permanent submitted in cassette F1A.

FROZEN SECTION DIAGNOSIS:
HIGH GRADE GLIOMA.

2. Received fresh for frozen section labeled with the patient's name and "brain tumor enhancing portion" consists of multiple tan-pink soft tissue fragments aggregating to 0.9 x 0.7 x 0.3 cm. A smear preparation is prepared and examined. Approximately 30% of the tissue submitted for frozen section with residual permanent submitted in cassette F2A. The remainder of the tissue is submitted in cassette 2B.

FROZEN SECTION DIAGNOSIS:
HIGH GRADE GLIOMA.

3. Received fresh for frozen section labeled with the patient's name and "brain tumor enhancing portion #2" consists of multiple irregular tan-pink to red soft tissue fragments, 0.8 x 0.7 x 0.3 cm. A smear preparation is prepared and examined. Approximately 40% of the tissue is submitted for frozen section with residual permanent submitted in cassette F3A. The remainder of the tissue is submitted in cassette 3B.

FROZEN SECTION DIAGNOSIS:
HIGH GRADE GLIOMA.

4. Received in formalin labeled with the patient's name and "brain tumor" consists of multiple irregular red-tan soft tissue fragments aggregating to

PAGE: 1

DATE RECEIVED:

---- CONTINUED----

[page 2 of 2]
ANATOMIC PATHOLOGY REPORT
PERMANENT CHART COPY
(Chart in Operative/Procedural Section)

NEUROPATHOLOGY REPORT

GROSS DESCRIPTION:

2.0 x 2.0 x 0.3 cm. Totally submitted in cassette 4A.

MICROSCOPIC DESCRIPTION:

1-4. Sections demonstrate a markedly hypercellular astrocytic neoplasm that diffusely infiltrates both the gray and white matter. Atypia is moderate to marked and mitoses vary from rare to numerous. Note that specimens 3 (enhancing portion #2) and 4 demonstrate the greatest atypia and mitotic activity. No definite microvascular proliferation is seen and no tumor necrosis is present.

DIAGNOSIS:

1-4. BRAIN TUMOR, INCLUDING ENHANCING PORTION AND ENHANCING PORTION #2,
BIOPSIES AND RESECTIONS:
ANAPLASTIC ASTROCYTOMA (WHO GRADE 3).

CPT:

Dictated by:
Verified by:

DATE COLLECTED:

PAGE: 2

DATE RECEIVED:

- END OF REPORT

Source: NCI Genomic Data Commons file 6fb3bb8a-e5d8-4b5b-9388-f7e97722c785 (TCGA-HT-A4DS.3E2FDB9A-0295-493E-8F8D-C501FA1B3172.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).